Somatic mutation profile of tumor specimen ALCH-B2OJ-TTP1-A (aliquot ALCH-B2OJ-TTP1-A-1-0-D-A77Z-36) from ALCHEMIST case ALCH-B2OJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.0 years (24,121 days).
Specimen ALCH-B2OJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b3e76ae-ee9e-4998-b32c-b69db347ea6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2OJ-NB1-A (Blood Derived Normal), aliquot ALCH-B2OJ-NB1-A-1-0-D-A77Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8f95a61-1100-4edf-b546-95cc3ab99b84

The open-access MAF lists 337 somatic variants for this specimen: 219 protein-altering or splice-affecting, 71 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 191, Silent 71, Intron 24, RNA 11, Frame Shift Del 10, Nonsense Mutation 8, 3'UTR 5, Splice Region 5, 5'UTR 4, Frame Shift Ins 2, 5'Flank 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPAST | c.1157A>G p.N386S | Missense Mutation (SNP) | VAF 68/284 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs121908514, CM044068; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 54/111 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGMO | c.949A>G p.I317V | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.222); catalogued as rs1379561160; called by muse, mutect2
- ALK | c.1673G>A p.G558E | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101201160, COSV66559733; called by muse, mutect2, varscan2
- ANKRD30B | c.3040T>C p.L1014= | Splice Region (SNP) | VAF 5/27 reads (19%) | catalogued as rs1431534099; called by muse, mutect2, varscan2
- ANKRD50 | c.74G>C p.C25S | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs550392767; called by muse, mutect2, varscan2
- ARHGEF6 | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 44/97 reads (45%) | catalogued as COSV51695235; called by muse, mutect2, varscan2
- ARMC3 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV53064797; called by muse, mutect2, varscan2
- BTBD8 | c.4346G>A p.G1449E (on ENST00000636805 / NM_001376131.1; = p.G936E on NM_015237.4) | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1360976156; called by muse, mutect2, varscan2
- C12orf42 | c.473C>G p.P158R | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs1379827410; called by muse, mutect2, varscan2
- CACNA1G | c.1032G>T p.W344C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100662483; called by muse, mutect2, varscan2
- CCDC141 | c.2024C>T p.T675M | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as COSV55377580; called by muse, mutect2, varscan2
- CD48 | c.26G>T p.C9F | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV100924305; called by muse, mutect2, varscan2
- CDK5RAP1 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 62/142 reads (44%) | catalogued as COSV59429132; called by muse, mutect2, varscan2
- CEP43 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV100835713, COSV62761283; called by muse, mutect2
- CLPTM1L | c.251C>A p.S84Y | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as rs529551617; called by muse, mutect2, varscan2
- CNTNAP3 | c.3506C>T p.S1169L | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV52672719; called by muse, mutect2
- COG5 | c.2255G>T p.R752L (on ENST00000347053 / NM_001379512.1; = p.R773L on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV51749685; called by muse, mutect2, varscan2
- COL7A1 | c.4787C>T p.P1596L | Missense Mutation (SNP) | VAF 70/124 reads (56%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.745); catalogued as rs981616124; called by muse, mutect2, varscan2
- CORIN | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV99903142; called by muse, mutect2, varscan2
- CSMD2 | c.2632C>G p.R878G | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53971764; called by muse, mutect2
- CX3CR1 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs756452900; called by muse, mutect2, varscan2
- DDX20 | c.338C>T p.T113I | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747625817, COSV100865893; called by muse, mutect2, varscan2
- DNAAF5 | c.2551G>A p.V851M | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs201895277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJA4 | c.610C>T p.R204C (on ENST00000343789; = p.R233C on NM_018602.3) | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1242423238, COSV100655080, COSV100655203; called by muse, mutect2, varscan2
- ERICH3 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as COSV58619270; called by muse, mutect2, varscan2
- FAM135B | c.4139G>T p.R1380L | Missense Mutation (SNP) | VAF 75/535 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52719126; called by muse, mutect2, varscan2
- FASLG | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.354); catalogued as COSV60681189; called by muse, mutect2, varscan2
- FILIP1L | c.3133C>G p.Q1045E (on ENST00000354552 / NM_182909.3; = p.Q805E on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/277 reads (18%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.675); catalogued as COSV58772002; called by muse, mutect2, varscan2
- FOXP2 | c.1228C>T p.H410Y | Missense Mutation (SNP) | VAF 136/527 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV63483938; called by muse, mutect2, varscan2
- GLUD2 | c.1402C>A p.L468M | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs879144657, COSV60151265; called by muse, mutect2
- GPR149 | c.560C>A p.S187Y | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99081401; called by muse, mutect2, varscan2
- GRIA4 | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV56884171, COSV56897286, COSV56922020; called by muse, mutect2, varscan2
- GRK3 | c.1173C>G p.F391L | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100151352; called by muse, mutect2, varscan2
- GTF3C2 | c.1621C>G p.L541V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99273254; called by muse, mutect2
- HIPK1 | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.188); catalogued as COSV65786905; called by muse, mutect2, varscan2
- HK3 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.666); catalogued as COSV52842900; called by muse, mutect2, varscan2
- IGF2R | c.1295T>A p.F432Y | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100808427; called by muse, mutect2, varscan2
- ITPKB | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); catalogued as COSV99684033; called by muse, mutect2, varscan2
- KCNJ8 | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53715816; called by muse, mutect2, varscan2
- LRP1B | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 97/308 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs961210138, COSV101255357, COSV67259299; called by muse, mutect2, varscan2
- MLIP | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as COSV51435743; called by muse, mutect2
- NARS1 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as COSV56876210; called by muse, mutect2, varscan2
- NCOA7 | c.407A>G p.N136S | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as rs1290494178, COSV99996936; called by muse, mutect2, varscan2
- OR2A7 | c.59C>A p.P20Q | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV71828471; called by muse, mutect2
- OR2T2 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100737869; called by muse, mutect2, varscan2
- OR56B1 | c.886A>T p.N296Y | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57723179; called by muse, mutect2, varscan2
- OR8J3 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56882691; called by muse, mutect2, varscan2
- OVCH1 | c.2871G>C p.L957F | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1263193282, COSV58964749; called by muse, mutect2, varscan2
- PCNX3 | c.4133C>G p.S1378C | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100856467; called by muse, varscan2
- PILRA | c.453G>T p.Q151H | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs373188096; called by muse, mutect2, varscan2
- PKD1 | c.9454C>T p.R3152W | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776866974; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCH1 | c.268G>T p.D90Y (on ENST00000340059 / NM_001130960.2; = p.D102Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/322 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100398213; called by muse, mutect2, varscan2
- PLD5 | c.1527C>A p.N509K (on ENST00000442594; = p.N447K on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/429 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.115); catalogued as rs903451526; called by muse, mutect2, varscan2
- PPP2R1A | c.203C>G p.A68G | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV59044220; called by muse, mutect2, varscan2
- PRKG1 | c.1243A>T p.T415S | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV64775455; called by muse, mutect2, varscan2
- RIPK4 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143003875; called by muse, mutect2, varscan2
- RPGRIP1L | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 83/363 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs565245381, COSV50914557; called by muse, mutect2, varscan2
- RUBCN | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); catalogued as rs200728428; called by muse, mutect2, varscan2
- SCN4A | c.2483G>A p.R828H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs556099012, COSV71125940; called by muse, mutect2, varscan2
- SDHAF2 | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 73/336 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1402726087; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDR42E2 | c.672G>A p.A224= | Splice Region (SNP) | VAF 10/81 reads (12%) | catalogued as rs1244883850; called by muse, mutect2, varscan2
- SIN3B | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1370973429; called by muse, mutect2, varscan2
- SLC22A18 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as COSV56540943; called by muse, mutect2, varscan2
- SLC4A7 | c.1501G>T p.A501S | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99839652; called by muse, mutect2, varscan2
- SLC6A5 | c.1555G>A p.V519I | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs570442943, COSV100116312, COSV54224567; called by muse, mutect2, varscan2
- SOGA1 | c.4340G>T p.R1447L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772420271; called by muse, mutect2, varscan2
- SRCAP | c.3995G>T p.R1332L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV99349014; called by muse, mutect2, varscan2
- TC2N | c.855+1G>T p.X285_splice | Splice Site (SNP) | VAF 51/304 reads (17%) | catalogued as COSV61746961; called by muse, mutect2, varscan2
- TPTE | c.893G>A p.R298K (on ENST00000618007 / NM_199261.4; = p.R280K on NM_199259.4) | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as rs749295156; called by muse, mutect2, varscan2
- TRIM58 | c.905C>A p.P302Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63569037, COSV63570091; called by muse, mutect2, varscan2
- TRIM63 | c.419C>G p.P140R | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100958168; called by muse, mutect2, varscan2
- TTN | c.49687G>C p.E16563Q (on ENST00000591111; = p.E9139Q on NM_003319.4) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | PolyPhen benign (0.434); catalogued as rs749849370, COSV59890435; called by muse, mutect2, varscan2
- TTYH3 | c.640C>A p.L214M | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1382870748; called by muse, mutect2, varscan2
- USP19 | c.1138dup p.W380Lfs*50 | Frame Shift Ins (INS) | VAF 11/21 reads (52%) | catalogued as COSV60044776; called by mutect2, pindel, varscan2
- ZFP36L2 | c.359G>C p.R120P | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99143575; called by muse, mutect2, varscan2
- ZFP62 | c.1466G>T p.R489L (on ENST00000502412 / NM_001377944.1; = p.R456L on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.038); catalogued as rs879072692, COSV104417890, COSV63091121; called by muse, mutect2, varscan2
- ZNF143 | c.794G>C p.R265P | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55180917; called by muse, mutect2, varscan2
- ZNF623 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV101513580; called by muse, varscan2
- ZP4 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.105); catalogued as rs1021008107, COSV63910918; called by muse, mutect2, varscan2
- AC007907.1 | n.310G>T | Splice Region (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2, varscan2
- AC092143.1 | c.1098G>A p.E366= | Splice Region (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- ACRBP | c.181C>G p.R61G | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- ADAMTS12 | c.1847A>G p.Y616C | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ADGRB1 | c.4380G>C p.E1460D | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ADGRG7 | c.196A>G p.T66A | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- AHCTF1 | c.1673T>G p.V558G (on ENST00000366508; = p.V532G on NM_015446.5) | Missense Mutation (SNP) | VAF 84/316 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); called by muse, varscan2
- AHNAK | c.7117A>G p.K2373E | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- AIRE | c.515A>C p.Q172P | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALPK2 | c.5440C>A p.H1814N | Missense Mutation (SNP) | VAF 53/289 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANO4 | c.2192C>G p.P731R (on ENST00000392977 / NM_001286615.2; = p.P696R on NM_178826.4) | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANO8 | c.1225G>T p.V409L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.349); called by muse, mutect2
- ANO8 | c.1223G>T p.S408I | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2
- AP002512.3 | c.1041C>G p.H347Q | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ARHGAP23 | c.2275G>T p.G759C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- BRINP2 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- C3orf62 | c.56G>C p.R19T | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CASP8 | c.340A>T p.R114* (on ENST00000432109 / NM_033355.3; = p.R146* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 81/344 reads (24%) | called by muse, mutect2, varscan2
- CCT7 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CDH10 | c.1792T>C p.C598R | Missense Mutation (SNP) | VAF 105/569 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH18 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 37/336 reads (11%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- CNGB1 | c.3307del p.A1103Rfs*13 | Frame Shift Del (DEL) | VAF 49/193 reads (25%) | called by mutect2, pindel, varscan2
- CRISPLD2 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DCHS1 | c.737del p.L246Rfs*45 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- DCUN1D3 | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DDX28 | c.1469G>C p.R490P | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLK2 | c.119G>T p.C40F | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DOCK5 | c.2767G>T p.V923L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- DRD4 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.634); called by mutect2, varscan2
- DTX4 | c.167A>G p.Y56C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYNC1H1 | c.3094G>A p.A1032T | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- EIF3A | c.3436G>T p.D1146Y | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- ETS2 | c.289_303del p.L97_K101del | In Frame Del (DEL) | VAF 47/120 reads (39%) | called by mutect2, pindel, varscan2
- FBXO5 | c.375G>C p.Q125H | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FFAR3 | c.146C>A p.A49D | Missense Mutation (SNP) | VAF 50/386 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); called by muse, mutect2
- FILIP1L | c.1378C>G p.Q460E (on ENST00000354552 / NM_182909.3; = p.Q220E on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/301 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAB4 | c.1267A>T p.S423C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2
- GPAM | c.176A>G p.K59R | Missense Mutation (SNP) | VAF 134/372 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- GPX5 | c.494C>A p.T165K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, varscan2
- GRK2 | c.1697C>A p.S566Y | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HIF1A | c.1138T>A p.S380T | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HSPA4 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ICAM5 | c.1350del p.V451Cfs*33 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- IFT80 | c.145C>G p.Q49E | Missense Mutation (SNP) | VAF 52/540 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.018); called by muse, mutect2
- IGKV2-30 | c.11C>A p.P4H | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ITPKA | c.902C>A p.T301K | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- KANK4 | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- KCMF1 | c.214G>T p.V72L | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- KCNJ3 | c.1092G>T p.M364I | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIDINS220 | c.2831del p.N944Ifs*5 | Frame Shift Del (DEL) | VAF 36/191 reads (19%) | called by mutect2, pindel, varscan2
- KLHL28 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- KLHL38 | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- KRTAP10-9 | c.215C>A p.T72N | Missense Mutation (SNP) | VAF 78/131 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- LHCGR | c.623T>A p.V208E | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- LINGO2 | c.976C>A p.L326I | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC38 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LRRTM4 | c.727T>A p.S243T | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAT2A | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MCHR2 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MICAL3 | c.1899_1900del p.D634Pfs*36 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by mutect2, pindel*, varscan2*
- MICB | c.667G>T p.V223L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, varscan2
- MLKL | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MOB4 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- MUC16 | c.20596G>C p.E6866Q | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- MUC5AC | c.1159G>T p.G387C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- NCK2 | c.566G>A p.S189N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NEK2 | c.899G>A p.S300N | Missense Mutation (SNP) | VAF 81/389 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHLH1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NUP210L | c.4391A>G p.D1464G | Missense Mutation (SNP) | VAF 68/286 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NXNL1 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.93); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- OBSCN | c.11359G>T p.G3787W | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.287); called by mutect2, varscan2
- OPN5 | c.584G>C p.G195A | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR1L8 | c.329A>G p.N110S | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- OR2T2 | c.862C>A p.P288T | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2T3 | c.572A>T p.K191M | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR4A47 | c.67A>G p.K23E | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- OR52D1 | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 57/231 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR5B21 | c.287C>A p.A96E | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PCDHA8 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.9727C>G p.Q3243E | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCM1 | c.3809C>A p.P1270Q | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- PDZD2 | c.2316G>A p.L772= | Splice Region (SNP) | VAF 38/171 reads (22%) | called by muse, mutect2, varscan2
- PHF24 | c.591G>C p.E197D | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIWIL1 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLCB1 | c.2181G>T p.W727C | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R1A | c.72G>T p.E24D | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- PRX | c.3527C>A p.S1176* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- PSMC1 | c.592A>C p.K198Q | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PTBP1 | c.1358C>T p.S453L (on ENST00000349038 / NM_031991.4; = p.S479L on NM_002819.5) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- PXDNL | c.182G>T p.R61I | Missense Mutation (SNP) | VAF 70/268 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- R3HDM1 | c.1466del p.P489Hfs*8 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- RAB28 | c.566A>T p.Q189L | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAI14 | c.1588G>C p.E530Q | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- RB1 | c.1233_1236del p.E413Vfs*3 | Frame Shift Del (DEL) | VAF 62/180 reads (34%) | called by mutect2, pindel, varscan2
- RELN | c.4802G>T p.S1601I | Missense Mutation (SNP) | VAF 84/249 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RHPN1 | c.1946G>A p.C649Y | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- RIMS2 | c.1654A>T p.T552S (on ENST00000666250 / NM_001348490.2; = p.T360S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/92 reads (65%) | SIFT tolerated (0.47); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RYR1 | c.7189A>T p.I2397F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SALL3 | c.3443G>T p.R1148L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SART1 | c.255_280del p.E87Gfs*5 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel
- SBF2 | c.740C>A p.P247H | Missense Mutation (SNP) | VAF 79/267 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN2A | c.2700G>A p.M900I | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SCN5A | c.2988del p.A997Pfs*148 (on ENST00000333535 / NM_198056.3; = p.A997Pfs*147 on NM_000335.5) | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | called by mutect2, varscan2
- SERPINA10 | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- SLC39A14 | c.509T>G p.L170R | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- SLC8B1 | c.793G>T p.V265F | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SLIT2 | c.1179G>T p.Q393H | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SMC6 | c.496A>G p.T166A | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SMURF1 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SORCS1 | c.1982T>A p.V661D | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- SPTBN5 | c.1100A>T p.E367V | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SRD5A1 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STAB2 | c.5119T>C p.S1707P | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- STARD8 | c.1097T>A p.V366D | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STARD9 | c.9184G>A p.A3062T | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- STARD9 | c.9271G>C p.E3091Q | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- STK10 | c.2575C>T p.Q859* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- TCF25 | c.838C>G p.Q280E | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.591); called by muse, varscan2
- TERB2 | c.236del p.N79Tfs*19 | Frame Shift Del (DEL) | VAF 38/220 reads (17%) | called by mutect2, pindel, varscan2
- TGIF2LX | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIGD5 | c.794dup p.C266Lfs*69 | Frame Shift Ins (INS) | VAF 10/25 reads (40%) | called by mutect2, pindel, varscan2
- TMEM245 | c.1522G>C p.E508Q | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- TMIGD1 | c.755A>T p.K252M | Missense Mutation (SNP) | VAF 70/295 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TRHDE | c.1438G>T p.G480C | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- TRIM51GP | c.551A>T p.H184L | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.21120C>G p.Y7040* (on ENST00000591111; = p.Y6113* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 44/227 reads (19%) | called by muse, mutect2, varscan2
- UBR3 | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- UBTFL1 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 113/382 reads (30%) | called by muse, mutect2, varscan2
- UTRN | c.7249A>C p.T2417P | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- UTRN | c.9020A>C p.E3007A | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- VPS13B | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); called by muse, varscan2
- WASHC4 | c.1742A>T p.Q581L | Missense Mutation (SNP) | VAF 78/385 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- XRCC4 | c.900G>T p.R300S (on ENST00000338635 / NM_022406.4; = p.K298N on NM_003401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZNF37A | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF438 | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- ZNF668 | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2
- ZNF716 | c.1375A>G p.T459A | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF793 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANTKMT | c.81G>T p.A27= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs769975671; called by muse, mutect2, varscan2
- ARHGAP21 | c.3993C>G p.L1331= | Silent (SNP) | VAF 25/78 reads (32%) | called by muse, mutect2, varscan2
- ARID5B | c.1011G>A p.T337= | Silent (SNP) | VAF 90/314 reads (29%) | catalogued as rs766671826, COSV99688989; called by muse, mutect2, varscan2
- C2orf42 | c.1011T>C p.P337= | Silent (SNP) | VAF 57/234 reads (24%) | called by muse, mutect2, varscan2
- CCHCR1 | c.76A>C p.R26= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV66161665; called by muse, mutect2, varscan2
- CD109 | c.3633G>A p.G1211= | Silent (SNP) | VAF 63/265 reads (24%) | called by muse, mutect2, varscan2
- CDRT1 | c.1134C>T p.N378= | Silent (SNP) | VAF 53/117 reads (45%) | catalogued as rs780395121; called by muse, mutect2, varscan2
- CNIH3 | c.63C>T p.I21= | Silent (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- COL26A1 | c.693G>T p.A231= (on ENST00000313669 / NM_001278563.3; = p.A229= on NM_133457.4) | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV58123915; called by muse, mutect2, varscan2
- COL2A1 | c.2457C>T p.G819= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as rs145833071; called by muse, mutect2, varscan2
- CSMD2 | c.2634T>A p.R878= | Silent (SNP) | VAF 34/172 reads (20%) | called by muse, mutect2
- CX3CL1 | c.693G>C p.A231= | Silent (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- DIAPH1 | c.1026G>T p.G342= | Silent (SNP) | VAF 74/266 reads (28%) | called by muse, mutect2, varscan2
- DPP6 | c.804C>A p.V268= (on ENST00000377770 / NM_001364500.2; = p.V206= on NM_001936.5) | Silent (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2, varscan2
- DSCAML1 | c.4107G>A p.L1369= (on ENST00000321322; = p.L1309= on NM_020693.4) | Silent (SNP) | VAF 22/103 reads (21%) | called by muse, mutect2, varscan2
- FAM13C | c.750C>T p.F250= | Silent (SNP) | VAF 70/245 reads (29%) | called by muse, mutect2, varscan2
- FBN2 | c.2808A>G p.E936= | Silent (SNP) | VAF 80/245 reads (33%) | catalogued as rs1468519610; called by muse, mutect2, varscan2
- FOXS1 | c.33C>A p.A11= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- FSIP2 | c.11715G>A p.R3905= | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- GP9 | c.369G>T p.P123= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV56624148; called by muse, mutect2, varscan2
- HAS1 | c.1338G>A p.A446= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs746209555, COSV99708577; called by muse, mutect2, varscan2
- IGF2R | c.1296T>C p.F432= | Silent (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- KCNH6 | c.351C>T p.N117= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as rs748485091; called by muse, mutect2, varscan2
- KIF2A | c.855T>C p.P285= | Silent (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
- LIPI | c.450C>A p.T150= | Silent (SNP) | VAF 89/178 reads (50%) | called by muse, mutect2, varscan2
- LRFN5 | c.1530G>T p.T510= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as COSV53279470; called by muse, mutect2, varscan2
- LRP5 | c.2934C>T p.N978= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs747039844, COSV53724216; called by muse, mutect2, varscan2
- MAP3K11 | c.1548C>G p.V516= | Silent (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- NDUFB5 | c.90G>T p.G30= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- NEUROD6 | c.363C>G p.V121= | Silent (SNP) | VAF 61/242 reads (25%) | called by muse, mutect2, varscan2
- NFE2L2 | c.309C>A p.S103= | Silent (SNP) | VAF 42/167 reads (25%) | called by muse, mutect2, varscan2
- NR5A2 | c.910C>T p.L304= (on ENST00000367362 / NM_205860.3; = p.L258= on NM_003822.5) | Silent (SNP) | VAF 72/303 reads (24%) | catalogued as rs777710720; called by muse, mutect2, varscan2
- NRXN3 | c.1830C>T p.N610= (on ENST00000557594 / NM_001272020.2; = p.N1034= on NM_004796.6) | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as rs138628835; called by muse, mutect2, varscan2
- NXF3 | c.111C>A p.V37= | Silent (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- OR10X1 | c.273G>T p.L91= | Silent (SNP) | VAF 28/215 reads (13%) | catalogued as rs755512209; called by muse, mutect2, varscan2
- OR5B21 | c.288A>G p.A96= | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as rs1448572143; called by muse, mutect2, varscan2
- OR5D13 | c.753T>A p.T251= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs764623697; called by muse, mutect2, varscan2
- PAPPA2 | c.480C>A p.A160= | Silent (SNP) | VAF 36/109 reads (33%) | called by muse, mutect2, varscan2
- PCCA | c.12C>T p.F4= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs759257021; called by muse, mutect2, varscan2
- PCLO | c.7926T>A p.S2642= | Silent (SNP) | VAF 31/154 reads (20%) | called by muse, mutect2, varscan2
- PDE1C | c.294G>A p.V98= | Silent (SNP) | VAF 41/192 reads (21%) | called by muse, mutect2, varscan2
- PHF21B | c.516C>T p.V172= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- PKHD1 | c.7302A>G p.A2434= | Silent (SNP) | VAF 86/331 reads (26%) | called by muse, mutect2, varscan2
- PLEC | c.3528G>T p.G1176= (on ENST00000322810 / NM_201380.4; = p.G1066= on NM_000445.5) | Silent (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- POLR3B | c.2739G>A p.Q913= | Silent (SNP) | VAF 98/394 reads (25%) | called by muse, mutect2, varscan2
- PRKAB1 | c.774G>A p.K258= | Silent (SNP) | VAF 49/177 reads (28%) | called by muse, mutect2, varscan2
- PRKACB | c.297G>A p.V99= | Silent (SNP) | VAF 36/174 reads (21%) | catalogued as COSV65760107; called by muse, mutect2, varscan2
- RBM12B | c.924T>C p.D308= | Silent (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- RUNX1T1 | c.819C>T p.G273= (on ENST00000265814 / NM_001198628.1; = p.G246= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/427 reads (10%) | catalogued as rs756137201, COSV56145186; called by muse, mutect2, varscan2
- SALL3 | c.2367C>T p.N789= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as rs1356369949; called by muse, mutect2, varscan2
- SALL3 | c.3444G>T p.R1148= | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- SCN1A | c.4788C>A p.R1596= (on ENST00000303395 / NM_001202435.3; = p.R1585= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/158 reads (30%) | catalogued as rs762836573; called by muse, mutect2, varscan2
- SEC31B | c.2040C>G p.S680= | Silent (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- SEMA3E | c.234A>G p.V78= | Silent (SNP) | VAF 59/262 reads (23%) | catalogued as rs757380130, COSV57096220; called by muse, mutect2, varscan2
- SERAC1 | c.471G>A p.E157= | Silent (SNP) | VAF 45/151 reads (30%) | called by muse, mutect2, varscan2
- SLC35G3 | c.462C>A p.L154= | Silent (SNP) | VAF 91/340 reads (27%) | called by muse, mutect2, varscan2
- SLC45A1 | c.1891C>T p.L631= | Silent (SNP) | VAF 41/122 reads (34%) | catalogued as COSV99238849; called by muse, mutect2, varscan2
- SOX3 | c.1161G>C p.S387= | Silent (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- SP6 | c.273C>A p.P91= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as rs1379050668; called by muse, varscan2
- SPTA1 | c.1437T>C p.H479= | Silent (SNP) | VAF 83/332 reads (25%) | called by muse, mutect2, varscan2
- TBC1D12 | c.1398C>T p.P466= | Silent (SNP) | VAF 15/91 reads (16%) | called by muse, mutect2, varscan2
- TDRD9 | c.2769A>T p.S923= | Silent (SNP) | VAF 53/187 reads (28%) | called by muse, mutect2, varscan2
- TGFBR3L | c.939G>A p.R313= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1397923171; called by muse, varscan2
- TRIM66 | c.354G>A p.Q118= | Silent (SNP) | VAF 61/202 reads (30%) | called by muse, mutect2, varscan2
- UBQLNL | c.603G>T p.T201= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as rs199511572, COSV66494003; called by muse, mutect2, varscan2
- WDR72 | c.2683T>C p.L895= | Silent (SNP) | VAF 26/166 reads (16%) | called by muse, mutect2, varscan2
- XRCC6 | c.934C>T p.L312= | Silent (SNP) | VAF 25/121 reads (21%) | called by muse, mutect2, varscan2
- ZBTB46 | c.582C>T p.S194= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs1215978325; called by muse, mutect2, varscan2
- ZFPM1 | c.2334C>T p.G778= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs1283858857; called by mutect2, varscan2
- ZNF483 | c.93G>A p.V31= | Silent (SNP) | VAF 30/242 reads (12%) | called by muse, mutect2, varscan2
- ZNF729 | c.54G>T p.V18= | Silent (SNP) | VAF 36/158 reads (23%) | called by muse, mutect2, varscan2
- AC024940.1 | n.4644G>T | RNA (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
- ACKR2 | c.-37-8108C>A | Intron (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- ADAM20P1 | n.768T>C | RNA (SNP) | VAF 5/21 reads (24%) | catalogued as rs748596706; called by muse, mutect2, varscan2
- AL590867.2 | n.257C>A | RNA (SNP) | VAF 58/296 reads (20%) | called by muse, mutect2, varscan2
- CALCOCO1 | c.260-367G>C | Intron (SNP) | VAF 5/18 reads (28%) | called by mutect2, varscan2
- CHRD | c.1933-66_1933-65insTGGCTGGG | Intron (INS) | VAF 7/42 reads (17%) | called by mutect2, pindel
- CMSS1 | chr3:100185766 G>T | 3'Flank (SNP) | VAF 105/315 reads (33%) | called by muse, mutect2, varscan2
- DCAF17 | c.*3159A>G | 3'UTR (SNP) | VAF 40/128 reads (31%) | catalogued as rs565191054; called by muse, mutect2, varscan2
- DEFB117 | n.24C>T | RNA (SNP) | VAF 22/176 reads (13%) | catalogued as rs565337551; called by muse, mutect2, varscan2
- DNAH5 | c.*14T>C | 3'UTR (SNP) | VAF 43/236 reads (18%) | catalogued as rs749171065; called by muse, mutect2, varscan2
- DPY19L2P2 | n.2670G>T | RNA (SNP) | VAF 42/256 reads (16%) | called by muse, mutect2, varscan2
- EFHC1 | c.*1963C>G | 3'UTR (SNP) | VAF 75/347 reads (22%) | catalogued as rs1027109792; called by muse, mutect2, varscan2
- ELMO2 | c.1884+216C>T | Intron (SNP) | VAF 31/113 reads (27%) | catalogued as COSV51685256; called by muse, mutect2, varscan2
- HHLA2 | c.-60G>A | 5'UTR (SNP) | VAF 24/134 reads (18%) | called by muse, mutect2, varscan2
- HNF1A | c.1309+167G>A | Intron (SNP) | VAF 30/139 reads (22%) | called by muse, mutect2, varscan2
- LSS | c.*39-891C>A | Intron (SNP) | VAF 85/142 reads (60%) | called by muse, mutect2, varscan2
- MGLL | c.-20-525A>G | Intron (SNP) | VAF 93/192 reads (48%) | called by muse, mutect2, varscan2
- MIR509-1 | n.65G>A | RNA (SNP) | VAF 29/61 reads (48%) | catalogued as rs782690043; called by muse, mutect2, varscan2
- MKRN9P | n.154G>T | RNA (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- MS4A4E | c.*7G>T | 3'UTR (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- MSX2 | c.379+13C>A | Intron (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- MUC19 | n.5787G>C | RNA (SNP) | VAF 73/260 reads (28%) | called by muse, mutect2, varscan2
- NADK | c.394-30G>T | Intron (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- OR1F2P | n.656A>G | RNA (SNP) | VAF 34/181 reads (19%) | catalogued as rs754005740; called by muse, mutect2, varscan2
- PDZD3 | c.-117C>A | 5'UTR (SNP) | VAF 20/82 reads (24%) | catalogued as rs1031492888, COSV99425029; called by muse, mutect2, varscan2
- PEX13 | c.92+312A>G | Intron (SNP) | VAF 31/126 reads (25%) | called by muse, mutect2, varscan2
- PHKA2 | c.-19G>T | 5'UTR (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- PIP5K1B | c.69+1470C>A | Intron (SNP) | VAF 84/395 reads (21%) | called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1647del | RNA (DEL) | VAF 52/277 reads (19%) | called by pindel, varscan2
- PRAMEF11 | c.-11C>A | 5'UTR (SNP) | VAF 19/44 reads (43%) | catalogued as COSV101463187; called by muse, mutect2, varscan2
- PTHLH | c.524+1378A>G | Intron (SNP) | VAF 14/98 reads (14%) | catalogued as COSV99571006; called by mutect2, varscan2
- RASGRP1 | chr15:38565343 C>A | 5'Flank (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159736 C>A | 5'Flank (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- RPGRIP1 | c.1763-55C>A | Intron (SNP) | VAF 31/98 reads (32%) | called by muse, mutect2, varscan2
- SLC12A5 | c.1464-24C>A | Intron (SNP) | VAF 14/50 reads (28%) | called by mutect2, varscan2
- SLC25A1 | c.302+36del | Intron (DEL) | VAF 12/44 reads (27%) | catalogued as rs1555923063; called by mutect2, varscan2
- SLC25A1 | c.302+35del | Intron (DEL) | VAF 10/54 reads (19%) | catalogued as rs782209746; called by mutect2*, pindel, varscan2*
- SLF2 | c.2042+151G>T | Intron (SNP) | VAF 25/106 reads (24%) | called by muse, mutect2, varscan2
- SLMAP | c.*2G>A | 3'UTR (SNP) | VAF 38/103 reads (37%) | called by muse, mutect2, varscan2
- SPAG6 | c.121+146T>C | Intron (SNP) | VAF 47/238 reads (20%) | called by muse, mutect2, varscan2
- TBC1D22A | c.1015+3333C>G | Intron (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- TBX3 | c.718-48C>T | Intron (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- TFAP2A | c.486+17C>T | Intron (SNP) | VAF 5/18 reads (28%) | catalogued as rs572036139; called by muse, mutect2, varscan2
- TMTC4 | c.1779+22C>A | Intron (SNP) | VAF 67/157 reads (43%) | called by muse, mutect2, varscan2
- TRIM51BP | n.814G>A | RNA (SNP) | VAF 31/52 reads (60%) | called by mutect2, varscan2
- VWA3B | c.1837-1029A>G | Intron (SNP) | VAF 33/146 reads (23%) | called by muse, mutect2, varscan2
- ZNF620 | c.24+2302A>T | Intron (SNP) | VAF 44/79 reads (56%) | called by muse, mutect2, varscan2
